Somatic mutation profile of tumor specimen C3N-01998-02 (aliquot CPT0139000010_1) from CPTAC case C3N-01998, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.2 years (25,293 days).
Specimen C3N-01998-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 346092d6-6b44-40a6-ad04-6ed4ac797ea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01998-71 (Blood Derived Normal), aliquot CPT0139020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2d1d67b-d3fe-4ecd-b5d6-a48ececa15d6

The open-access MAF lists 51 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Intron 7, Nonsense Mutation 3, Splice Site 1, 3'UTR 1, Translation Start Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 90/1030 reads (9%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2
- ACVR2A | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 31/392 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV54020876; called by muse, mutect2
- ARID1A | c.2686G>T p.E896* | Nonsense Mutation (SNP) | VAF 23/230 reads (10%) | catalogued as COSV61371402, COSV61375225; called by mutect2, varscan2
- FEM1A | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 98/1224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764367324; called by muse, mutect2
- HGFAC | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs754623818, COSV66976859; called by muse, mutect2
- IGF2BP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs1024617698, COSV51736242; called by muse, mutect2
- IQCA1 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 50/889 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs755904682; called by muse, mutect2
- MGAT5 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99924214; called by muse, mutect2
- MYO18B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 38/449 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774090650, COSV59124937, COSV59152211; called by muse, mutect2
- PLXND1 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 45/530 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs760772408; called by muse, mutect2
- SMARCA4 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 25/375 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1060502073, COSV60790239; ClinVar: uncertain significance; called by muse, mutect2
- SMPD3 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs759989372, COSV54711209; called by muse, mutect2
- SPATA31D1 | c.4624G>A p.V1542I | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs747668068, COSV100782409, COSV61200420; called by muse, mutect2
- TCN2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 48/617 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV53191763; called by muse, mutect2
- ZFP36L1 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60544530; called by muse, mutect2, varscan2
- ZFPM2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 108/1361 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765404652, COSV65873778; called by muse, mutect2
- ZNF568 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.185); catalogued as rs148872903, COSV71278456; called by muse, mutect2
- AFG1L | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2
- ANO3 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- ATM | c.8268G>A p.K2756= | Splice Region (SNP) | VAF 34/467 reads (7%) | called by muse, mutect2
- DCP2 | c.1172G>T p.C391F | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2
- DNAH9 | c.10841T>A p.I3614N | Missense Mutation (SNP) | VAF 29/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPCAT1 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 19/500 reads (4%) | called by muse, mutect2
- MFSD1 | c.1288+2T>C p.X430_splice | Splice Site (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- POSTN | c.2431G>A p.D811N | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.515); called by muse, mutect2
- SPG7 | c.1918G>A p.A640T (on ENST00000268704; = p.A647T on NM_003119.4) | Missense Mutation (SNP) | VAF 37/409 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- STIP1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SUMO2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2
- TEX14 | c.1007G>T p.S336I (on ENST00000240361 / NM_001201457.2; = p.S330I on NM_031272.5) | Missense Mutation (SNP) | VAF 41/430 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TRIM34 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFPM2 | c.1898A>G p.D633G | Missense Mutation (SNP) | VAF 85/996 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- BCL10 | c.30G>A p.E10= | Silent (SNP) | VAF 46/832 reads (6%) | called by muse, mutect2
- CPLX4 | c.210G>A p.R70= | Silent (SNP) | VAF 41/568 reads (7%) | called by muse, mutect2
- DISC1 | c.1360A>C p.R454= | Silent (SNP) | VAF 34/701 reads (5%) | called by muse, mutect2
- GRK1 | c.897G>A p.A299= | Silent (SNP) | VAF 46/758 reads (6%) | catalogued as rs372619279; called by muse, mutect2
- HYAL2 | c.105C>T p.P35= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as rs376665287; called by muse, mutect2, varscan2
- MED1 | c.744T>C p.S248= | Silent (SNP) | VAF 56/624 reads (9%) | called by muse, mutect2
- PPAN-P2RY11 | c.1983C>T p.A661= | Silent (SNP) | VAF 24/291 reads (8%) | catalogued as rs145891760; called by muse, mutect2
- PROKR2 | c.327C>T p.F109= | Silent (SNP) | VAF 36/502 reads (7%) | catalogued as rs780924864, COSV54085659, COSV54087202; called by muse, mutect2
- SLC2A5 | c.1002C>T p.F334= | Silent (SNP) | VAF 23/283 reads (8%) | catalogued as rs1215704368, COSV66236994; called by muse, mutect2
- SPTBN4 | c.4767A>T p.A1589= | Silent (SNP) | VAF 38/394 reads (10%) | called by muse, mutect2
- THSD7A | c.1887C>T p.A629= | Silent (SNP) | VAF 23/314 reads (7%) | catalogued as rs1268628813; called by muse, mutect2
- BANP | c.1345-416C>T | Intron (SNP) | VAF 52/570 reads (9%) | catalogued as rs1396565367, COSV53740863; called by muse, mutect2
- CDH13 | c.484-36411C>A | Intron (SNP) | VAF 16/458 reads (3%) | called by muse, mutect2
- DUSP13 | c.*283C>G | 3'UTR (SNP) | VAF 14/407 reads (3%) | catalogued as COSV57814126; called by muse, mutect2
- NLRC5 | c.4154+273G>C | Intron (SNP) | VAF 19/257 reads (7%) | called by muse, mutect2
- PPFIA2 | c.304-54439C>T | Intron (SNP) | VAF 43/563 reads (8%) | called by muse, mutect2
- SDCBP2 | c.225+150G>A | Intron (SNP) | VAF 32/656 reads (5%) | catalogued as rs541924836; called by muse, mutect2
- SFXN5 | c.945+4074G>A | Intron (SNP) | VAF 30/486 reads (6%) | called by muse, mutect2
- TRAF3IP3 | c.1312+15T>C | Intron (SNP) | VAF 44/691 reads (6%) | catalogued as COSV99162264; called by muse, mutect2
- ZNF971P | n.957G>A | RNA (SNP) | VAF 57/800 reads (7%) | called by muse, mutect2
